Somatic mutation profile of tumor specimen C3L-00921-02 (aliquot CPT0064150007) from CPTAC case C3L-00921, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Age at diagnosis: 66.1 years (24,157 days).
Specimen C3L-00921-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13adee19-e515-42cf-8ece-536d594b5938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00921-31 (Blood Derived Normal), aliquot CPT0065390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc2f2e9c-f477-42a2-a519-e29832919485

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Intron 5, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1, RNA 1, Splice Site 1, In Frame Del 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 93/173 reads (54%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRPF1 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758572778; called by muse, mutect2, varscan2
- C19orf53 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs779977463; called by muse, mutect2, varscan2
- C2orf16 | c.5515C>T p.R1839C | Missense Mutation (SNP) | VAF 68/351 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1233876003, COSV100820631; called by muse, mutect2, varscan2
- CD79A | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs782043875, COSV99701975; called by muse, mutect2, varscan2
- CMKLR1 | c.409C>T p.R137C (on ENST00000312143 / NM_001142344.2; = p.R135C on NM_004072.3) | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148287464; called by muse, mutect2, varscan2
- EGF | c.3560C>A p.S1187* | Nonsense Mutation (SNP) | VAF 52/279 reads (19%) | catalogued as COSV54479745, COSV99490449; called by muse, mutect2, varscan2
- EIF2S3B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs761146576, COSV59372994; called by muse, mutect2, varscan2
- EYA4 | c.579C>T p.Y193= | Splice Region (SNP) | VAF 79/390 reads (20%) | catalogued as rs747954279, COSV62052786; called by muse, mutect2, varscan2
- FOLR2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs749858709, COSV99995614; called by muse, mutect2, varscan2
- GLG1 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs1203720881, COSV52663797; called by muse, mutect2, varscan2
- GPR101 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs779782375; called by muse, mutect2, varscan2
- GRID1 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs143286261, COSV60012100; called by muse, mutect2
- INO80B | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV51970154; called by muse, mutect2, varscan2
- JPH2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 125/657 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV65901663; called by muse, mutect2, varscan2
- KDM6B | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 113/566 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); catalogued as rs545723280, COSV99640587; called by muse, mutect2, varscan2
- LARP6 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760940752, COSV54579125; called by muse, mutect2, varscan2
- MYH4 | c.4491T>G p.D1497E | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.235); catalogued as COSV55116741; called by muse, mutect2, varscan2
- NCDN | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.446); catalogued as rs752708609, COSV61934916; called by muse, mutect2, varscan2
- OBSCN | c.3968C>A p.A1323E | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.225); catalogued as rs1480062293; called by muse, mutect2, varscan2
- RET | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.833); catalogued as rs1483605155, CM1111630, CS1110912, COSV60693777; called by muse, mutect2, varscan2
- SLC4A2 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749678950; called by muse, mutect2, varscan2
- TBX18 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV100858447; called by muse, mutect2, varscan2
- TEKT4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782558219, COSV54626009; called by muse, mutect2, varscan2
- TENM4 | c.6712C>T p.R2238W | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779398356, COSV53648374; called by muse, mutect2, varscan2
- TRMT10C | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs368035344; called by muse, mutect2, varscan2
- UNC45B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs779255426, COSV52098471; called by muse, mutect2, varscan2
- ZMIZ1 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.141); catalogued as rs769108026, COSV57901931; called by muse, mutect2, varscan2
- ABCA13 | c.7860C>A p.S2620R | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- AMBN | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANO9 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ARHGAP35 | c.2834dup p.N946Efs*11 | Frame Shift Ins (INS) | VAF 24/135 reads (18%) | called by mutect2, varscan2
- ATP7A | c.3901G>T p.D1301Y | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP47 | c.4313dup p.N1439Efs*2 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- ENKUR | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LINC00587 | n.267+1_267+2del | Splice Site (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- MORF4L2 | c.867A>C p.*289Cext*24 | Nonstop Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- NETO1 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRAMEF18 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 50/599 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RNF213 | c.3905A>C p.E1302A | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ROCK2 | c.3883C>G p.R1295G | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- RPS6KA5 | c.1252_1257del p.P418_F419del | In Frame Del (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- STAP2 | c.1191G>C p.K397N (on ENST00000594605 / NM_001013841.2; = p.K443N on NM_017720.3) | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF526 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CDC20B | c.1536G>A p.T512= (on ENST00000381375 / NM_001170402.1; = p.T508= on NM_152623.2) | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs749147711, COSV57051424; called by muse, mutect2, varscan2
- COL6A3 | c.4074G>A p.E1358= | Silent (SNP) | VAF 62/292 reads (21%) | called by muse, mutect2, varscan2
- GNAS | c.1560C>T p.S520= | Silent (SNP) | VAF 80/407 reads (20%) | catalogued as rs781228486, COSV100007219; called by muse, mutect2, varscan2
- HECTD3 | c.2547C>T p.C849= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs758014490; called by muse, mutect2, varscan2
- MAGEL2 | c.555G>A p.P185= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs754419261; called by muse, mutect2, varscan2
- MKRN1 | c.1371C>T p.D457= | Silent (SNP) | VAF 90/664 reads (14%) | catalogued as rs374563168; called by muse, mutect2, varscan2
- NEUROG3 | c.174G>A p.P58= | Silent (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- OR5J2 | c.621C>T p.A207= | Silent (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- PCDHA3 | c.183G>A p.P61= | Silent (SNP) | VAF 82/450 reads (18%) | catalogued as COSV65365877; called by muse, mutect2, varscan2
- RPGRIP1L | c.2658G>A p.S886= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs775153934; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RTCB | c.1023T>C p.D341= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs370431155; called by muse, mutect2, varscan2
- SLC7A11 | c.243C>T p.T81= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs373244994; called by muse, mutect2, varscan2
- SOBP | c.1695C>T p.N565= | Silent (SNP) | VAF 75/434 reads (17%) | called by muse, mutect2, varscan2
- TTC7B | c.2394C>T p.H798= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs537489789; called by muse, varscan2
- CLCN7 | c.981+45C>T | Intron (SNP) | VAF 51/193 reads (26%) | catalogued as rs778426912; called by muse, mutect2, varscan2
- ESYT1 | c.1474-15T>G | Intron (SNP) | VAF 43/181 reads (24%) | called by muse, mutect2, varscan2
- KIAA1328 | c.59-26A>C | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1887+22G>A | Intron (SNP) | VAF 26/155 reads (17%) | catalogued as rs200354718, COSV64860473; called by muse, mutect2, varscan2
- PIP5K1C | c.-27C>T | 5'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SPATA31C2 | n.1838C>T | RNA (SNP) | VAF 77/329 reads (23%) | catalogued as rs1412780149; called by muse, mutect2, varscan2
- TMEM63A | c.676-13A>G | Intron (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
